Surgical pathology report (de-identified scan), TCGA case TCGA-06-6694, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-6694-01A (Primary Tumor).

[REDACTED]

[REDACTED]

06-6694

PATHOLOGICAL DIAGNOSIS:

LEFT PARIETAL BIOPSY: GLIOSARCOMA. PROLIFERATIVE INDEX (MIB-1): 30%
TO 40%. [REDACTED]

Operation/Specimen: L. parietal lobe.

Clinical History and Pre-Op Dx:

GROSS PATHOLOGY: Received in formalin and labeled with the
patient's
name, MRN and "Lt. parietal brain tumor", is a 3.5 x 2.0 x 1.5 cm.
gray-tan tissue fragment. The specimen is serially sectioned through
its short axis to reveal a firm, tan to gray-tan surface. All
submitted (6-9).
[REDACTED]

MICROSCOPIC: Sections show a gliosarcoma with characteristic biphasic
pattern of glial and sarcomatous components. The distinctive biphasic
picture is well demonstrated with GFAP which stains the glial
component
and reticulin stain which show the sarcomatous component. Patchy
areas
of necrosis are seen in the glial component.
[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file f88deec3-3a94-4e90-8124-d5f28b3339b4 (TCGA-06-6694.BFD32E29-52A6-4CCF-AD99-0C595E3127EC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).